Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3KX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3KX-01A (Primary Tumor).

[page 1 of 3]
105-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium c54.1
12/21/11

Reviewed (date):	12/21/11	12/19/11

Surgical Pathology Consultation Report

Specimen(s) Received

1. Lymph-Node: Right Pelvic.
2. Uterus: Uterus, cervix, BSO fresh

Diagnosis

1. Lymph nodes, right pelvic, dissection:
- Three lymph nodes, negative for carcinoma (0/3)
2. Uterus, cervix, bilateral fallopian tubes and ovaries:
- ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, FIGO GRADE 3/3, (see synoptic report)
- Myometrial invasion present (inner half)
- Lymphovascular invasion not identified
- Cervix, negative for carcinoma, but tumour involves lower uterine segment

Other:

- Uterine leiomyomata
- Left fallopian tube with paratubal cysts
- Right fallopian tube with no histopathologic abnormality
- Bilateral ovaries with no histopathologic abnormality

Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Site:	Posterior endometrium
Tumor Size:	Greatest dimension: 7 cm
Histologic Type:	Endometrioid adenocarcinoma, not otherwise characterized

[page 2 of 3]
Surgical Pathology Consultation Report

Histologic Grade: FIGO grade 3
Myometrial Invasion: Present
Myometrial thickness: 28 mm
Less than 50% myometrial invasion
Involvement of Cervix: Not involved
Extent of Involvement of Other Organs:
Right ovary not involved
Left ovary not involved
Right fallopian tube not involved
Left fallopian tube not involved
Lymph-Vascular Invasion: Not identified
TNM Descriptors: Not applicable
Primary Tumor (pT): pT1a (IA): Tumor limited to endometrium or invades less than 1/2 of the myometrium
Regional Lymph Nodes (pN): pNX: Regional lymph nodes cannot be assessed
Pelvic lymph nodes examined: 3
Pelvic lymph nodes involved: 0
Para-aortic lymph nodes examined: 0
Para-aortic lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Other: Uterine leiomyomata

Electronically verified by:

Clinical History ENDOMETRIAL CA

Gross Description

1. The specimen container is labeled with the patient's name and as "Lymph node: Right pelvic". The specimen consists of a piece of fibroadipose tissue measuring 3.0 x 2.5 x 1.5 cm. Within the tissue are 3 possible lymph nodes that range from 0.4 to 2.2 cm. Representative sections, 22 submitted in toto:

1A 2 lymph nodes
1B 1 lymph node

2. The specimen container is labeled with the patient's name and as "Uterus, cervix, BSO fresh". The specimen consists of a total hysterectomy specimen with attached bilateral salpingo-oophorectomy. The specimen has a fresh weight of 135.1 g. The uterus and cervix measures 9.3 cm SI x 6.5 cm ML x 3.5 cm AP. The cervix has a maximum diameter of 2.0 cm. The external os measures 0.8 cm and is oval. The right fallopian tube measures 4.5 x 0.3 cm. The right ovary measures 2.7 x 1.7 x 0.8 cm. The left fallopian tube measures 5.0 x 0.3 cm. The left ovary measures 2.9 x 0.1 x 0.7 cm.

The uterine serosa demonstrates a pink-tan glistening appearance with some fibrous adhesions noted on the posterior aspect. The right-sided peri-adnexal tissue shows gross hemorrhage. The exocervix is pink-tan with focal areas of bright orange discoloration. The anterior aspect shows very little squamous epithelium. There is tumor protruding through the os. The endocervical canal measures 3.7 cm in length. The endometrial cavity measures 3.5 cm SI x 5.2 cm from cornua to cornua. The endometrium is completely involved on the posterior aspect by a friable, papillary tan tumor that measures 7.0 cm SI x 5.2 cm from cornua to cornua. The anterior endometrium has a trabeculated appearance with a focal area of tumor on the left lateral aspect. The tumor has a maximum depth of 2.2 cm, extends to the outer half of the myometrium and comes to within 0.7 cm of the posterior serosa. The myometrium is unremarkable. Both fallopian tubes show fimbria. The outer surface of the ovaries is smooth. The cut surface of each ovary demonstrates an unremarkable parenchyma. Multiple pieces of tissue are stored frozen. Representative sections, fimbria and remainder of fallopian tubes and ovaries in toto:

2A-2B anterior cervix to anterior lower uterine segment, bisected
2C-2D full thickness sections anterior endomyometrium
2E-2F posterior cervix to posterior lower uterine segment, bisected

[page 3 of 3]
Surgical Pathology Consultation Report

2G-2H full thickness section posterior endomyometrium, bisected
2I-2J full thickness section posterior endomyometrium, bisected
2K right fimbria, longitudinally sectioned
2L right fallopian tube, serially sectioned
2M-2N right ovary
2O left fimbria, longitudinally sectioned
2P left fallopian tube, serially sectioned
2Q-2R left ovary

Source: NCI Genomic Data Commons file b4f71469-8327-4807-a793-4b897175c2c0 (TCGA-EO-A3KX.BB1CD473-0D98-414E-801B-09037E1BF43E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).